Somatic mutation profile of tumor specimen TARGET-15-SJMPAL011911-03A (aliquot TARGET-15-SJMPAL011911-03A-01D) from TARGET case TARGET-15-SJMPAL011911, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,731 days).
Specimen TARGET-15-SJMPAL011911-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b6c92c2-31f0-4865-ac94-56e8c8d02c18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL011911-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL011911-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5a9404d-2db1-4a4e-8884-bb360abffb03

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARF | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775019489, COSV57548232, COSV57548286; called by muse, mutect2, varscan2
- FBN1 | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs539103389, CM096445, COSV57323932; ClinVar: uncertain significance; called by muse, mutect2
- GRIN2B | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV101663122; called by muse, mutect2, varscan2
- NPAP1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs1170974294, COSV61505991; called by muse, mutect2, varscan2
- RUNX1 | c.538_539insCC p.R180Pfs*5 (on ENST00000344691 / NM_001001890.3; = p.R207Pfs*5 on NM_001754.5) | Frame Shift Ins (INS) | VAF 17/33 reads (52%) | catalogued as COSV55880386, COSV99038740; called by mutect2, pindel, varscan2
- THOC6 | c.194G>C p.S65T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.468); catalogued as rs1455090114; called by muse, mutect2, varscan2
- TMPRSS15 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362308542, COSV53043850; called by muse, mutect2, varscan2
- WT1 | c.1096_1099delinsACTTTTTAGGA p.L366Tfs*3 | Nonsense Mutation (INS) | VAF 35/88 reads (40%) | catalogued as COSV60072365; called by pindel, varscan2*
- BRINP2 | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLCF1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, varscan2
- HERC5 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.44); called by muse, varscan2
- MAD1L1 | c.1827G>T p.E609D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- MAPK6 | c.1954C>A p.L652I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, varscan2
- PIPOX | c.957C>A p.C319* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- RYR1 | c.9914C>A p.T3305K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SDK1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by mutect2, varscan2
- SRPRA | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, varscan2
- ZNF84 | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2
- BOK | c.267G>A p.A89= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs771523960, COSV59192555; called by muse, mutect2, varscan2
- DNAJB4 | c.423A>T p.G141= | Silent (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- EFCAB11 | c.126C>T p.D42= | Silent (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- KCNAB2 | c.385C>A p.R129= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- LINGO3 | c.1443G>T p.V481= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- MAPK4 | c.1536C>T p.D512= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- SIMC1 | c.933G>A p.Q311= (on ENST00000443967 / NM_001308196.1; = p.Q330= on NM_001308195.2) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- ACP1 | c.231+132C>A | Intron (SNP) | VAF 3/34 reads (9%) | catalogued as COSV55244375; called by muse, mutect2
- ARF3 | c.*583G>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- TPK1 | c.185+15159G>A | Intron (SNP) | VAF 22/59 reads (37%) | catalogued as rs1375349156; called by muse, mutect2, varscan2
